Gene-level copy-number profile of tumor specimen ALCH-B3FW-TTP1-A from ALCHEMIST case ALCH-B3FW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,185 days).
Specimen ALCH-B3FW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c90c124-e8c1-4fe8-a897-67f69faf13a6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/7fe16cb7-2a49-4e44-847b-b70c5a1e442a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 19,251; copy number 2: 33,570; copy number 3: 3,609; copy number 4: 1,831; copy number 5: 194; copy number 6: 135; copy number 7: 205; copy number 9: 11; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:17,717,625–17,749,978, 1 gene: LINC02810.
- chr2:44,921,077–44,946,071, 11 genes (within-gene range 0–2): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr5:139,644,460–139,683,882, 3 genes: AC113361.1, CXXC5, CXXC5-AS1.
- chr5:180,982,273–181,006,727, 2 genes: ARPP19P1, BTNL3.
- chr7:128,830,406–128,859,274, 1 gene (within-gene range 0–3): FLNC.
- chr7:142,871,208–142,885,745, 1 gene (within-gene range 0–2): TRPV6.
- chr8:33,513,475–33,523,291, 2 genes (within-gene range 0–1): SNORD13, AC091144.1.
- chr9:124,481,236–124,507,420, 1 gene: NR5A1.
- chr9:135,693,407–135,795,508, 2 genes: SOHLH1, KCNT1.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr15:25,104,642–25,108,352, 3 genes (within-gene range 0–1): SNORD116-28, SNORD116-29, SNORD116-30.
- chr15:25,176,832–25,225,284, 27 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr15:84,389,729–84,395,903, 3 genes: AC243562.2, RN7SL417P, AC243562.1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:4,693,694–4,695,859, 1 gene: NUDT16L1.
- chr16:30,023,334–30,027,736, 1 gene (within-gene range 0–2): C16orf92.
- chr16:66,908,122–66,975,149, 7 genes: CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–1): AC099521.2.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr17:19,020,656–19,064,136, 4 genes (within-gene range 0–1): GRAP, AC003957.1, SNORD3B-1, SNORD3B-2.
- chr17:82,018,702–82,065,887, 9 genes: CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L.
- chr19:531,760–549,924, 2 genes: CDC34, GZMM.
- chr19:11,538,767–11,550,323, 1 gene: CNN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 547 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,409,560–31,239,887, 19 genes, copy number 5–7: AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1.
- chr11:1,947,278–1,989,920, 2 genes, copy number 13: MRPL23, MRPL23-AS1.
- chr19:23,914,876–41,261,766, 526 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
